Somatic mutation profile of cancer-model specimen HCM-BROD-0231-C25-85M (3D Organoid, passage 4; aliquot HCM-BROD-0231-C25-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0231-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 68.9 years (25,156 days).
Specimen HCM-BROD-0231-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14ee1f2a-0b4e-4e3b-b885-2ccdb84419c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0231-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0231-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0237deda-b62f-41ec-90e5-ed90f510a82e

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, In Frame Del 2, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 137/139 reads (99%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ARID1A | c.3391C>G p.Q1131E | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61376561, COSV61380004; called by mutect2, varscan2
- CARD11 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 290/623 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1298741148, COSV67802261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRXCR1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 29/470 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.637); catalogued as rs577521620, COSV67670049; called by muse, mutect2
- MAN2A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs1359989748; called by muse, mutect2, varscan2
- NRXN1 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 120/237 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453687; called by muse, mutect2, varscan2
- NT5DC2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1268012937; called by muse, mutect2
- POTEJ | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 127/473 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs764378487; called by muse, mutect2, varscan2
- SEC61A1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 218/507 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs767658338, COSV54578190; called by muse, mutect2, varscan2
- SHMT2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 288/580 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs760592358, COSV61073422; called by muse, mutect2, varscan2
- SLC6A9 | c.1653C>T p.Y551= (on ENST00000360584 / NM_201649.4; = p.Y497= on NM_006934.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 156/360 reads (43%) | catalogued as rs200915117, COSV62212040; called by muse, mutect2, varscan2
- SLFN14 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 172/383 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1274661246; called by muse, mutect2, varscan2
- TBC1D10B | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 263/536 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374035939, COSV59768069; called by muse, mutect2, varscan2
- USH2A | c.9526C>A p.P3176T | Missense Mutation (SNP) | VAF 162/308 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.261); catalogued as COSV56356532; called by muse, mutect2, varscan2
- AANAT | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 106/422 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1A | c.3398_3401del p.P1133Lfs*27 | Frame Shift Del (DEL) | VAF 220/240 reads (92%) | called by pindel, varscan2
- ATP1A4 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 182/397 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 82/258 reads (32%) | called by mutect2, pindel, varscan2
- C11orf80 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 349/796 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2
- C12orf42 | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 342/777 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DHX40 | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 213/426 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- EPS8L2 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 234/485 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 67/369 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IFNK | c.533A>T p.Y178F | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- LRRFIP2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 155/157 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MTR | c.2519T>A p.M840K | Missense Mutation (SNP) | VAF 159/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMPCA | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 317/626 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R36 | c.424_426del p.T142del | In Frame Del (DEL) | VAF 113/123 reads (92%) | called by pindel, varscan2
- SLCO3A1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 218/408 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIM31 | c.12dup p.Q5Afs*81 | Frame Shift Ins (INS) | VAF 177/252 reads (70%) | called by mutect2, pindel, varscan2
- USF3 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFHX4 | c.4022T>G p.V1341G | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BCAR1 | c.1584T>C p.N528= | Silent (SNP) | VAF 301/604 reads (50%) | called by muse, mutect2, varscan2
- CR2 | c.2172G>T p.V724= | Silent (SNP) | VAF 116/254 reads (46%) | called by muse, mutect2, varscan2
- MACF1 | c.13368C>G p.R4456= (on ENST00000372915; = p.R2389= on NM_012090.5) | Silent (SNP) | VAF 408/413 reads (99%) | called by muse, mutect2, varscan2
- NFIC | c.909C>T p.P303= | Silent (SNP) | VAF 12/356 reads (3%) | catalogued as rs1203834517; called by muse, mutect2
- PDGFRA | c.2985C>T p.N995= | Silent (SNP) | VAF 186/443 reads (42%) | catalogued as rs138801854; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A45 | c.609G>A p.T203= | Silent (SNP) | VAF 176/380 reads (46%) | catalogued as rs370780233; called by muse, mutect2, varscan2
- TBC1D25 | c.522C>T p.G174= | Silent (SNP) | VAF 168/171 reads (98%) | called by muse, mutect2, varscan2
- TBX4 | c.939C>T p.L313= | Silent (SNP) | VAF 353/719 reads (49%) | catalogued as rs777644345, COSV53606573, COSV53610218; called by muse, mutect2, varscan2
- UCK1 | c.318G>A p.E106= | Silent (SNP) | VAF 18/494 reads (4%) | catalogued as COSV64736204; called by muse, mutect2
- VPS13D | c.10101C>T p.V3367= | Silent (SNP) | VAF 30/510 reads (6%) | called by muse, mutect2
- GH2 | c.457-33C>A | Intron (SNP) | VAF 204/428 reads (48%) | catalogued as COSV60426287, COSV60426704; called by muse, mutect2
- TBC1D29P | n.2788G>A | RNA (SNP) | VAF 227/485 reads (47%) | catalogued as rs761058128, COSV70434072; called by muse, varscan2
